Somatic mutation profile of tumor specimen 0DJHH4 from CCDI case PBBWJS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Desmoplastic melanoma, malignant; Tissue or organ of origin: Skin of scalp and neck; Age at diagnosis: 5.2 years (1,907 days).
Specimen 0DJHH4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38cd4137-0230-4003-b46a-77a264318f4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHDY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1970b611-db64-4814-a24c-60693d082724

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 5'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA7 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 95/247 reads (38%) | catalogued as COSV65178722; called by muse, varscan2
- LAPTM5 | c.669G>A p.E223= | Silent (SNP) | VAF 104/242 reads (43%) | called by muse, varscan2
- MCOLN1 | c.330G>C p.S110= | Silent (SNP) | VAF 90/256 reads (35%) | called by muse, varscan2
- ABCC1 | c.-82G>A | 5'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, varscan2
- PDE8A | c.-99C>T | 5'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
